Somatic mutation profile of tumor specimen TCGA-CJ-4913-01A (aliquot TCGA-CJ-4913-01A-01D-1429-08) from TCGA case TCGA-CJ-4913, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 45.9 years (16,757 days).
Specimen TCGA-CJ-4913-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc18e841-220e-4c31-b994-94216a43ff3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4913-11A (Solid Tissue Normal), aliquot TCGA-CJ-4913-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f248eaa-9e18-4e1b-94d4-385074e12260

The open-access MAF lists 57 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, Frame Shift Ins 4, Nonsense Mutation 4, RNA 1, In Frame Del 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.3499A>T p.T1167S | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54029650; called by muse, mutect2, varscan2
- AGPAT5 | c.859A>G p.I287V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV53447012; called by muse, mutect2, varscan2
- AMER2 | c.1535A>G p.E512G | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63437558; called by muse, mutect2, varscan2
- AVPR1A | c.758C>A p.S253* | Nonsense Mutation (SNP) | VAF 35/212 reads (17%) | catalogued as COSV54546637, COSV54547971; called by muse, mutect2, varscan2
- BACH2 | c.2027G>A p.C676Y | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.942); catalogued as rs780989553, COSV57592623; called by muse, mutect2
- BAZ2A | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1199067676, COSV51636811; called by muse, mutect2, varscan2
- CHMP2A | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV53396910; called by muse, mutect2
- COQ5 | c.176T>A p.V59E | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56019065; called by muse, mutect2, varscan2
- DAXX | c.199T>A p.F67I | Missense Mutation (SNP) | VAF 53/319 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV56469373; called by muse, mutect2, varscan2
- FAN1 | c.2546T>G p.I849S | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV62950642; called by muse, mutect2
- FBN1 | c.31del p.L11Wfs*7 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | catalogued as CD042199; called by mutect2, pindel, varscan2
- FOXO1 | c.976G>C p.G326R | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65425125; called by muse, mutect2
- FOXR2 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.432); catalogued as COSV59258483; called by mutect2, varscan2
- IREB2 | c.1694A>G p.Y565C | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV51922763; called by muse, mutect2
- KLHL25 | c.1475G>T p.S492I | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs1415955539, COSV61995139; called by muse, mutect2, varscan2
- LSP1 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61134384; called by muse, varscan2
- MAX | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV52416961; called by muse, varscan2
- MRPS5 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55533672; called by muse, mutect2, varscan2
- MYO5C | c.1842G>C p.K614N | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as COSV55906273; called by muse, mutect2, varscan2
- OR10AG1 | c.612G>T p.L204F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV56631118, COSV56632931; called by muse, mutect2, varscan2
- OR4D6 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55659208, COSV55659790; called by muse, mutect2
- PBRM1 | c.3046G>T p.E1016* (on ENST00000296302 / NM_001366071.2; = p.E991* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV56276607, COSV56300412; called by muse, mutect2, varscan2
- PLAU | c.999A>T p.K333N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65641361; called by muse, mutect2, varscan2
- POLD1 | c.2636C>A p.S879Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54530956; called by muse, mutect2, varscan2
- RANBP6 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs530947222, COSV52389466; called by muse, mutect2, varscan2
- RNF40 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765188561, COSV61214851; called by muse, mutect2, varscan2
- ROCK1 | c.362dup p.W122Lfs*25 | Frame Shift Ins (INS) | VAF 14/69 reads (20%) | catalogued as rs35810558; called by mutect2, pindel, varscan2
- SEC16A | c.2701A>T p.S901C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); catalogued as COSV51528249; called by muse, mutect2, varscan2
- SERPINA12 | c.375G>T p.Q125H | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV57943677, COSV57943932; called by muse, mutect2, varscan2
- SLC44A5 | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV63765054; called by muse, mutect2, varscan2
- TAF5L | c.1041C>G p.S347R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV51080121; called by muse, mutect2, varscan2
- TFDP2 | c.645G>C p.Q215H (on ENST00000489671 / NM_001178139.2; = p.Q155H on NM_006286.5) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57707804; called by muse, mutect2, varscan2
- TFDP3 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV59536932; called by muse, mutect2, varscan2
- UBR1 | c.3913G>T p.G1305* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV51929831; called by muse, mutect2, varscan2
- ZDHHC9 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.561); catalogued as COSV64096627; called by muse, mutect2, varscan2
- ZNF154 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as COSV70745064; called by muse, mutect2
- ZNF395 | c.1129T>A p.S377T | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV60428682; called by muse, mutect2, varscan2
- GTSF1 | c.242_244del p.V82del | In Frame Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3639dup p.E1214Rfs*6 (on ENST00000296302 / NM_001366071.2; = p.E1189Rfs*6 on NM_018313.5) | Frame Shift Ins (INS) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- RPL22 | c.267dup p.Y90Ifs*6 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- SYCP2 | c.3257C>A p.S1086* | Nonsense Mutation (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ZNF100 | c.402dup p.Y135Ifs*7 | Frame Shift Ins (INS) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- BAIAP2 | c.108G>A p.K36= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV104414980, COSV58335502; called by muse, mutect2
- DNAI4 | c.2304G>A p.E768= | Silent (SNP) | VAF 8/111 reads (7%) | catalogued as rs1317133796, COSV64029516; called by muse, mutect2
- FBXO38 | c.192G>A p.V64= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs763779865, COSV57027835; called by muse, mutect2, varscan2
- FER | c.2217A>G p.S739= | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as COSV55291386; called by muse, mutect2
- NSG1 | c.63C>G p.G21= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV67575064; called by muse, mutect2, varscan2
- PEG3 | c.3903A>C p.V1301= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV55633950; called by muse, mutect2, varscan2
- PGD | c.970C>A p.R324= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as COSV54621455, COSV54622307; called by muse, mutect2, varscan2
- RNPEPL1 | c.1719G>A p.L573= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV54372644; called by muse, mutect2, varscan2
- SERPINE1 | c.948G>A p.L316= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV56169687; called by muse, mutect2
- SPNS1 | c.1089C>T p.L363= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as COSV57954758; called by muse, mutect2, varscan2
- TIMM44 | c.972C>T p.I324= | Silent (SNP) | VAF 6/125 reads (5%) | catalogued as COSV54491461; called by muse, mutect2
- TRMO | c.495A>G p.S165= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- UNC79 | c.4833C>A p.S1611= (on ENST00000393151 / NM_001346218.2; = p.S1434= on NM_020818.5) | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV56388256; called by muse, mutect2, varscan2
- ZNF184 | c.1317T>C p.T439= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV53004324; called by muse, mutect2
- LINC02870 | n.221C>T | RNA (SNP) | VAF 16/148 reads (11%) | catalogued as rs770083654; called by muse, mutect2, varscan2
